Somatic mutation profile of tumor specimen TCGA-CH-5788-01A (aliquot TCGA-CH-5788-01A-11D-1576-08) from TCGA case TCGA-CH-5788, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.1 years (25,233 days).
Specimen TCGA-CH-5788-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78aa2d3b-64ad-4e48-9627-873a0e02e176.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5788-10A (Blood Derived Normal), aliquot TCGA-CH-5788-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f24e46f-2e88-4d83-b3cf-e41f92b5c479

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 24, Silent 9, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 152/401 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1057519968, COSV61652911, COSV61653817; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2912C>T p.T971M (on ENST00000404938 / NM_001163941.2; = p.T526M on NM_178559.6) | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs764723410, COSV51702685; called by muse, mutect2, varscan2
- ADCY6 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs1442691683, COSV57168564; called by muse, mutect2, varscan2
- CCNG1 | c.288T>A p.C96* | Nonsense Mutation (SNP) | VAF 64/154 reads (42%) | catalogued as COSV61652109; called by muse, mutect2, varscan2
- CDCP2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs768204684, COSV61284251; called by muse, mutect2, varscan2
- CDK13 | c.2098C>G p.R700G | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51701735, COSV99475101; called by muse, mutect2, varscan2
- CHD1 | c.4877G>C p.R1626T | Missense Mutation (SNP) | VAF 73/91 reads (80%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV52341462; called by muse, mutect2, varscan2
- COL11A1 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV62180726, COSV62186463; called by muse, mutect2, varscan2
- DHRS13 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as COSV60455390; called by muse, mutect2, varscan2
- DPP8 | c.958A>G p.M320V (on ENST00000341861 / NM_001320875.2; = p.M304V on NM_017743.6) | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs1461340797, COSV55679807; called by muse, mutect2
- ERCC2 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67263940; called by muse, mutect2, varscan2
- FCGBP | c.2927G>A p.G976D | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as rs777632186; called by muse, mutect2, varscan2
- FES | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.98); catalogued as COSV51577422; called by muse, mutect2, varscan2
- HJURP | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as COSV64978963; called by muse, mutect2
- KIF14 | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as rs1277100723, COSV66262221; called by muse, mutect2, varscan2
- MFSD8 | c.1095G>C p.Q365H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV56551522; called by muse, mutect2, varscan2
- MSL2 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53865521; called by muse, mutect2, varscan2
- MYO9A | c.3090C>A p.F1030L | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV61852753; called by muse, mutect2, varscan2
- NTRK1 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs1295528046, COSV62326261; called by muse, mutect2, varscan2
- OTOGL | c.2066G>T p.C689F (on ENST00000547103; = p.C680F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 198/507 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72006795; called by muse, mutect2, varscan2
- SARDH | c.1462C>A p.L488M | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV64098680, COSV64100008; called by muse, mutect2, varscan2
- SP1 | c.2090G>A p.R697K (on ENST00000327443 / NM_138473.3; = p.R690K on NM_003109.1) | Missense Mutation (SNP) | VAF 156/364 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV59403609; called by muse, mutect2, varscan2
- SRSF1 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51965403; called by muse, mutect2, varscan2
- STAMBP | c.282A>G p.K94= | Splice Region (SNP) | VAF 44/100 reads (44%) | catalogued as COSV59897583; called by muse, mutect2, varscan2
- TPPP2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs775487462, COSV100069458, COSV53875465; called by muse, mutect2, varscan2
- ZNF713 | c.1250G>T p.C417F (on ENST00000633730 / NM_001366796.2; = p.C430F on NM_182633.3) | Missense Mutation (SNP) | VAF 116/212 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV70056799; called by muse, mutect2, varscan2
- MAPKAPK3 | c.28_49del p.G10Lfs*23 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel
- CACNG2 | c.606C>T p.I202= | Silent (SNP) | VAF 162/406 reads (40%) | catalogued as COSV55636232; called by muse, varscan2
- CHD1 | c.5043G>A p.Q1681= | Silent (SNP) | VAF 62/88 reads (70%) | catalogued as rs772098911, COSV52341452; called by muse, mutect2
- CREBBP | c.6795G>A p.A2265= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as rs748072121, COSV52127630; ClinVar: likely benign; called by muse, mutect2, varscan2
- HIPK3 | c.2922T>C p.H974= | Silent (SNP) | VAF 45/199 reads (23%) | catalogued as COSV57563270; called by muse, mutect2, varscan2
- LGR6 | c.633C>T p.S211= (on ENST00000367278 / NM_001017403.1; = p.S159= on NM_021636.3) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV55151524; called by muse, mutect2, varscan2
- PCDHB7 | c.714C>T p.N238= | Silent (SNP) | VAF 9/152 reads (6%) | catalogued as rs782421028, COSV50760211; called by muse, mutect2
- PRTG | c.1947G>A p.Q649= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as COSV66838578; called by muse, mutect2, varscan2
- SLC9A5 | c.2625C>T p.T875= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV55362828; called by muse, mutect2
- TRPA1 | c.1854C>T p.G618= | Silent (SNP) | VAF 60/184 reads (33%) | catalogued as rs1255337905, COSV51564454; called by muse, mutect2, varscan2
